Surgical pathology report (de-identified scan), TCGA case TCGA-DJ-A3UR, project TCGA-THCA (Thyroid Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DJ-A3UR-01A (Primary Tumor).

[page 1 of 3]
bw 4/30/12

Head & Neck
Head And Neck

Date of Procedure:
Date of Receipt:
Date of Report:
Account #:
Billing Type:
Additional Copy to:

Ref. Source:

Clinical Diagnosis & History:

Papillary thyroid cancer.

Specimens Submitted:

- 1: SP: Pretracheal and superior mediastinal lymph nodes (fs)
- 2: SP: Total thyroidectomy
- 3: SP: Delphian node
- 4: SP: Right paratracheal node

DIAGNOSIS:

1. SP: Pretracheal and superior mediastinal lymph nodes, excision (fs):
- Metastatic papillary thyroid carcinoma in two of three lymph nodes (2/3).
- The largest metastatic lymph node measures 0.5 cm in greatest dimension and the metastatic focus measures 0.45 cm in greatest dimension.
- No extranodal extension is identified.

2. SP: Total thyroidectomy:

Tumor Type:

Four foci of papillary thyroid carcinoma, follicular and microcarcinoma variants. One the microcarcinoma has tall cell features.

99% follicular variant per TSS per

Histologic Grade:

Well differentiated

ICD-O-3

Mitotic Activity:

Not identified

Carcinoma, papillary, follicular variant

Tumor Necrosis:

Not identified

8340/3

Tumor Location:

Left lobe
Right lobe
Isthmus

Site: thyroid, NOS

C73.9 5-2-12 RD

Tumor Size:

Tumor foci range from 0.2 to 1 cm.

Tumor Encapsulation:

The largest nodule in the right lobe is completely surrounded by a capsule but the smaller nodules in the left lobe and isthmus are not encapsulated.

Capsular Invasion:

No capsular invasion in the encapsulated nodule.

Blood Vessel Invasion:

Not identified

[page 2 of 3]
Extrathyroid Extension:

One of the microcarcinoma invades extra-thyroid fibroadipose tissue.

Surgical Margins:

Free of tumor

Adenoma(s) (away from the carcinoma):

Not Identified

Non-Neoplastic Thyroid:

Exhibits nodular hyperplasia
of mild degree

Parathyroid Glands:

Not identified

3. SP: Delphian node, excision:

-Two benign lymph nodes (0/2).

4. SP: Right paratracheal node, excision:

-Metastatic papillary thyroid carcinoma in two of two lymph nodes (2/2). The largest metastatic node is 0.18 cm and the largest metastatic focus is 0.07 cm.
-No extranodal extension is identified.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1). The specimen is received fresh for frozen section consultation, labeled "Three tracheal and superior mediastinal lymph nodes" and consists of three lymph nodes measuring 0.3 cm, 0.3 cm, and 0.4 cm in greatest dimension. Entirely submitted for frozen section.

Summary of sections:

FSC - frozen section control

2). The specimen is received fresh, labeled "Total thyroidectomy" and consists of a thyroid weighing 19 g. The specimen is previously inked and sectioned. The right lobe measures 4.5 x 2.0 x 1.0 cm, the left lobe measures 4.0 x 2.0 x 1.0 cm and the isthmus measures 2.5 x 0.8 x 0.3 cm. The external surface is covered by a thin fibrous capsule and attached muscle anteriorly. The posterior surface of the specimen is inked black, and the anterior is inked blue. Sectioning reveals 1.0 x 0.8 x 0.8 cm well circumscribed tan ovoid nodule in the right lobe abutting the anterior capsule. Sectioning through the remaining tissue reveals three white nodules in the isthmus, left, right, lobes averaging 0.3 x 0.2 x 0.2 cm. The remaining thyroid parenchyma is red tan and beefy. Representative sections of the specimen are submitted for and a photograph has been taken. The remaining tissue is serially sectioned and entirely submitted.

Summary of sections:

N - nodule

RL - right lobe

LL - left lobe

IS - isthmus

[page 3 of 3]
3). The specimen is received in formalin, labeled "Delphian node" and consists of a single lymph node measuring 0.9 X 0.8 X 0.3 cm. The lymph node is entirely submitted.

Summary of sections:
LN - lymph node

4). The specimen is received in formalin, labeled "right peritracheal node" and consists of a single fatty soft tissue fragment measuring 0.3 x 0.2 x 0.1 cm. The specimen is entirely submitted.

Summary of sections:
U - undesignated

Summary of Sections:

Part 1: SP: Pretracheal and superior mediastinal lymph nodes (fs)

Block	Sect. Site	PCs
1	fsc	1

Part 2: SP: Total thyroidectomy

Block	Sect. Site	PCs
2	I	3
9	LL	11
3	N	4
8	RL	10

Part 3: SP: Delphian node

Block	Sect. Site	PCs
1	LN	1

Part 4: SP: Right paratracheal node

Block	Sect. Site	PCs
1	U	1

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

- 1) FROZEN SECTION DIAGNOSIS: SP: PRETRACHEAL AND SUPERIOR MEDIASTINAL LYMPH NODES (FS):
METASTATIC PAPILLARY THYROID CARCINOMA
PERMANENT DIAGNOSIS: SAME

Source: NCI Genomic Data Commons file a462a1ab-53ee-4eb9-b9f6-978efa665ca6 (TCGA-DJ-A3UR.BB1A0D13-F803-43E4-AD87-34E37B6932FD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).